Gene-level copy-number profile of tumor specimen TCGA-CR-7377-01A from TCGA case TCGA-CR-7377, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Overlapping lesion of lip, oral cavity and pharynx; AJCC pathologic stage: Stage IVA; Tumor grade: G3; Age at diagnosis: 58.5 years (21,371 days).
Specimen TCGA-CR-7377-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-HNSC.0896cb74-deee-46cd-ac66-19f50e4e9503.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-CR-7377-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 804 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/f91469e6-c244-4453-aa33-67aebfe60920

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 11; copy number 1: 11,259; copy number 2: 40,649; copy number 3: 6,628; copy number 4: 612; copy number 5: 318; copy number 6: 271; copy number 7: 71.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-CR-7377-01A-11D-2010-01): tumor purity 0.24, ploidy 2.04, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 7 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:231,767,464–231,847,706, 2 genes (within-gene range 0–2): AL136171.2, AL136171.1.
- chr2:197,569–209,892, 1 gene: AC079779.1.
- chr3:196,739,857–196,832,647, 1 gene (within-gene range 0–3): PAK2.
- chr3:196,784,980–196,785,086, 1 gene: RNU6-42P.
- chr5:174,724,582–174,730,896, 1 gene: MSX2.
- chr5:174,751,734–174,751,787, 1 gene: MIR4634.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 660 genes in 8 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:221,133,865–223,776,018, 42 genes, copy number 7 (within-gene range 3–7): AL445466.1, LINC02817, AL360013.2, AL360013.3, AL360013.1, AL360013.4, DUSP10, LINC01655, RNU6-403P, LINC02257, LINC02474, LINC01705, AL356108.1, QRSL1P2, AL513314.1, CICP13, AL513314.2, RNU6-791P, AL592148.2, HHIPL2, TAF1A, TAF1A-AS1, MIA3, AL592148.1, AL592148.3, AIDA, BROX, FAM177B, AL392172.1, DISP1, NDUFB1P2, AL929091.1, TLR5, AL359979.2, AL359979.1, SUSD4, RNU4-57P, CCDC185, CAPN8, SNRPEP10, RNU6-1248P, CAPN2.
- chr1:224,434,660–225,882,380, 21 genes, copy number 5 (within-gene range 2–5): CNIH3, AKR1B1P1, CNIH3-AS2, DNAJB6P6, AL596330.1, CNIH3-AS1, LINC02813, AL391811.1, DNAH14, LBR, LINC02765, AC092811.1, ENAH, AC099066.2, AC099066.1, RNU6-1304P, SRP9, AC099066.3, EPHX1, AL591895.1, TMEM63A.
- chr5:57,395,060–57,619,816, 4 genes, copy number 7: AC025470.2, SALL4P1, ACTBL2, LINCR-0003.
- chr10:25,647,570–27,100,494, 25 genes, copy number 7 (within-gene range 3–7): GPN3P1, LINC00836, HIRAP1, RNA5SP306, RNU6-632P, AL358612.1, MYO3A, GAD2, AL355798.1, APBB1IP, RNA5SP307, AL160287.1, FAM238A, AL390961.1, FAM238B, SELENOOLP, AL390961.3, PDSS1, HSPA8P3, AL390961.2, ABI1, AL139404.1, RNU6-946P, FAM238C, ANKRD26.
- chr10:33,759,713–42,874,060, 121 genes, copy number 5 (broad region; genes not listed).
- chr11:65,823,022–71,818,238, 246 genes, copy number 6 (within-gene range 4–6) (broad region; genes not listed).
- chr12:66,767–991,190, 25 genes, copy number 6: IQSEC3, AC026369.3, AC026369.1, AC026369.2, AC007406.3, SLC6A12, AC007406.1, SLC6A12-AS1, SLC6A13, AC007406.2, AC007406.4, KDM5A, CCDC77, B4GALNT3, NINJ2, AC006205.2, RNU7-103P, AC006205.1, NINJ2-AS1, LINC02455, WNK1, RNU4ATAC16P, AC004765.1, RAD52, AC004803.1.
- chr19:9,291,140–12,294,887, 176 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 8,864. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
